Surgical pathology report (de-identified scan), TCGA case TCGA-Q1-A6DV, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site University of Oklahoma HSC, specimen TCGA-Q1-A6DV-01A (Primary Tumor).

[page 1 of 4]
RUN DATE:
RUN TIME:
BY:

LABORATORY
Specimen Inquiry

PAGE:1

SPEC #:
STATUS:

Obtained:
Received:

Subm Dx:

CLINICAL HISTORY:
CERVICAL CANCER

SPECIMEN/PROCEDURE:

1. UTERUS - VAGINAL MARGIN, BILATERAL TUBES AND OVARIES
2. LYMPH NODE, PELVIC - RIGHT
3. LYMPH NODE, PELVIC - LEFT
4. VAGINA - ADDITIONAL MARGIN

path ICD-O-3
Adenocarcinoma 1103 8/40/3
c/cf Adenocarcinoma, mucinous
endocervical type 8482/3
Site: Endocervix C53.0
JPD 6/3/13

IMPRESSION:

1) UTERUS:

CERVIX:

- . Adenocarcinoma of endocervix, usual (mucin depleted) type, grade 2 (1.1 cm), invading 8 mm where the wall measures 13 mm.
- . The tumor is focally necrotic and xanthogranulomatous inflammation is present.
- . Focal squamous severe dysplasia is also present.
- . No vascular space invasion is identified.
- . The vaginal cuff and deep stromal (radial) margins are negative.

PARAMETRIAL TISSUES, BILATERAL:

- . Benign fibroadipose tissue.
- . No tumor is identified.
- . Two lymph nodes are negative for tumor (0/2).

ENDOMETRIUM:

- . Benign inactive endometrium.

MYOMETRIUM:

- . Superficial adenomyosis.

FALLOPIAN TUBES, BILATERAL:

- . No pathologic diagnosis.

2) RIGHT PELVIC LYMPH NODES:

- . Ten lymph nodes are negative for tumor (0/10).

3) LEFT PELVIC LYMPH NODES:

- . Five lymph nodes are negative for tumor (0/5).

4) ADDITIONAL VAGINAL MARGIN:

- . Squamous mucosa and submucosa with no evidence of tumor or dysplasia.

UTERINE CERVIX: TRACHELECTOMY, HYSTERECTOMY, PELVIC EXENTERATION CASE SUMMARY

SPECIMEN

Cervix
Uterus corpus
Right ovary

** CONTINUED ON NEXT PAGE **

[page 2 of 4]
IMPRESSION: (continued)

Left ovary
Right fallopian tube
Left fallopian tube
Vagina (cuff)
Other (specify): Parametria

PROCEDURE

Radical hysterectomy

TUMOR SIZE

Greatest dimension: 1.1 cm
Additional dimensions: 1.0 x 0.7 cm

TUMOR SITE

Left superior quadrant (12-3 o'clock)
Right inferior quadrant (6-9 o'clock)

HISTOLOGIC TYPE

Adenocarcinoma
Mucinous
Endocervical type

HISTOLOGIC GRADE

G2: Moderately differentiated

MARGINS

Resection Margin

Margins uninvolved by invasive carcinoma

LYMPH-VASCULAR INVASION

Not identified

PATHOLOGIC STAGING (pTNM [FIGO])

PRIMARY TUMOR (pT)

pT1b1[IB1]: Clinically visible lesion < 4.0 cm in greatest dimension

REGIONAL LYMPH NODES (pN)

pN0: No regional lymph node metastasis

DISTANT METASTASIS (pM)

Not applicable

ADDITIONAL PATHOLOGIC FINDINGS

Intraepithelial neoplasia (specify type and grade): Squamous CIN III

Pathologic TNM (AJCC 7th edition): pT1b1 N0 M

Dictated by:

Entered:

[page 3 of 4]
GROSS DESCRIPTION:

1. Received fresh, labeled with the patient's name and medical record number and uterus vaginal margin, bilateral tubes and ovaries, is a 165 gram specimen including an unopened uterus (8.8 x 6.8 x 5.8 cm), right fallopian tube (6.3 cm in length 0.4 cm in diameter), left fallopian tube (6.1 cm in length 0.4 cm in diameter). No ovaries are grossly identified. The exocervix (2.6 x 2.3 cm) is covered by smooth glistening white mucosa. The external os is circular and measures 0.7 cm in diameter. The endocervical canal (3.4 cm in length) has a tan herringbone mucosa. The endometrial cavity (2.2 cm from cornu to cornu, 4.3 cm in length) has a tan/pink hemorrhagic endometrial lining.

The 12:00 portion of the cervix is designated as the anterior most portion of the cervix. There is a 1.0 x 1.1 x 0.7 cm ulcerated lesion located at the 12:00 to 2:00 direction. The lesion is 0.4 cm away from the nearest vaginal cuff margin. A frozen section is performed on and research taken from the lesion. The remainder of the frozen section is submitted for permanent sections.

There endometrial mucosa is pink/gray. The myometrium is unremarkable and not thickened (2.7 cm in maximum thickness). The serosa is shiny and glistening without adhesions. A representative sections are submitted.

The fallopian tubes are patent and have fimbriated ends. Representative sections are submitted.

Ink code:
blue-anterior
black-posterior

FROZEN SECTION DIAGNOSIS: Vaginal cuff margin 12:00-2:00 margin is benign. The diagnosis is discussed with at on

CASSETTE SUMMARY:

CASSETTE 1F: frozen section of 12:00 to 2:00 vaginal margin, en face (not true margin, see part 4)

CASSETTE 1A: right fallopian tube

CASSETTE 1B: left fallopian tube 1C, 1D: anterior endomyometrium

CASSETTE 1E, 1G: posterior endomyometrium

CASSETTE 1H-1K: 3:00-6:00 cervix and vaginal margin

CASSETTE 1L-1N: 6:00-9:00 cervix and vaginal margin

CASSETTE 1P-1R: 9:00-12:00 cervix and vaginal margin

CASSETTE 1S-1U: 12:00-3:00 cervix and vaginal margin with lesion

CASSETTE 1V: right parametrium

CASSETTE 1W: left parametrium

2. Received without fixative labeled "right pelvic lymph nodes" and with the patient's name, is an aggregate of irregular portions of yellow-tan lobulated adipose tissue, 6 x 2.5 x 1.1 cm. The specimen is dissected for lymph nodes, there are 10 red-tan ovoid lymph nodes identified, ranging from 0.3 x 0.2 x 0.1 cm in 1.8 x 1 x 0.3 cm. All lymph nodes identified are submitted as follows:

Cassette 2A: 3 lymph nodes

Cassette 2B: 4 lymph nodes 2C: 3 lymph nodes

3. Received without fixative labeled "left pelvic lymph nodes" and with the patient's name, is an aggregate of irregular portions of yellow-tan lobulated adipose tissue, 3 x 2.5 x 1 cm. The specimen is dissected for lymph nodes, there are 5 tan ovoid lymph nodes

** CONTINUED ON NEXT PAGE **

[page 4 of 4]
GROSS DESCRIPTION: (continued)

identified, ranging from 0.6 x 0.4 x 0.3 cm to 3 x 1 x 0.3 cm. All lymph nodes identified are submitted as follows:

Cassette 3A: 3 lymph nodes

Cassette 3B: One lymph node 3C: One lymph node

4. Received fresh, labeled with the patient's name, medical record number and "additional vaginal margin" is a 8.7 x 0.8 x 0.4 cm unoriented strip of tan skin. No gross lesion is identified. The specimen is entirely submitted in cassettes 4A and 4C.

Dictated by:

Entered:

COPIES TO:

No Primary or Family Physician

CPT Codes:

FS INITIAL/88331, PATHOLOGY TISSUE, LYMPH NODE, REGIONAL RESECT/88307/2,
UTERUS W/VO ADNEXAE, TUMOR-88309, H&E-88313, VAGINAL BIOPSY/88305

ICD9 Codes:

180.9

Resident Physician:

I have personally reviewed the material
(specimen/slide) and approve this final report.

Electronically Signed by: _____

Physicians

** END OF REPORT **

Source: NCI Genomic Data Commons file a552b4be-039f-4b0b-ba42-b5f6595413a6 (TCGA-Q1-A6DV.B42DEC07-001A-4766-BFD6-DE67D04ABA65.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).